Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GN, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GN-01B (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, renal cell
Chromophobe Type 8317/3
Site @ Kidney NOS C64.9
J 9/24/13

Surgical Pathology Report

Diagnosis:

Kidney, left, laparoscopic nephrectomy

- Renal cell carcinoma, chromophobe type, grade 2 (of 4, Fuhrman classification), 3.6 cm diameter, without angiolymphatic invasion, with focal extracapsular extension, inked surgical margins not involved.

Clinical History: yo male presents with a left kidney mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: laparoscopic nephrectomy

Side of specimen: left

Size and weight of specimen: 17 x 16 x 4 cm; 610 grams

Presence/absence of adrenal gland: absent

Tumor description/site: The tumor site is left upper pole/posterior surface; it is a circumscribed, lobulating appearing tan/orange mass with focal bands of white fibrosis. The surface overlying the mass is inked green. The hilar structures are inked purple.

Tumor size: 3.6 x 3.3 x 2.8 cm

Presence/absence of multicentricity: absent, one focus

Confinement/non-confinement to the kidney: confined but abutting the renal capsule

Extent of invasion:

Perirenal adipose tissue: does not grossly involve

Gerota's fascia: does not grossly involve

Renal vein: does not grossly involve

Ureter: does not grossly involve

Other organs: n/a

Surgical margins:

Perirenal adipose tissue: negative grossly

[page 2 of 3]
Renal vein: negative grossly
Renal artery: negative grossly
Ureter: negative grossly

Description of kidney away from tumor: slightly hemorrhagic appearing

Lymph nodes (hilar): none identified

Other significant findings: none

Tissue submitted for special investigations:

Digital photograph taken: No

Block Summary:

A1 - ureter margin

A2 - hilar vessels

A3 - uninvolved kidney

A4-A6 - tumor at green ink

A7 - tumor with adjacent normal

A8 - tumor with adjacent normal

A9 - additional tumor

Light Microscopy:

Light microscopic examination is performed by Dr.

Histologic tumor type/subtype: Renal cell carcinoma, chromophobe type CD10(+), CK7(+), Colloidal iron(+). Dr. concurs.

Histologic grade (if applicable): Grade 2

Tumor size (greatest dimension): 3.6 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: Present (block A7)

Gerota's fascia: Not present

Renal vein: Not involved

Ureter: Not involved

Venous (large vessel) Not involved

Lymphatic (small vessel): Not involved

Depth of invasion: N/A

Adjacent organs: Not received

[page 3 of 3]
Histologic assessment of surgical margins:

Perirenal adipose tissue: Negative

Gerota's fascia: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Adrenal gland: Not received

Lymph nodes: Not received

Other significant findings: None

AJCC Staging:

pT3a pNx pMx

Source: NCI Genomic Data Commons file 56780d17-d229-431e-8bd1-72a3bd26b0eb (TCGA-UW-A7GN.1B881218-C0F8-4717-88E2-CAF9D1BFEA95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).